Surgical pathology report (de-identified scan), TCGA case TCGA-FB-A78T, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-A78T-01A (Primary Tumor).

[page 1 of 3]
Surgical Date:

Gross Description: A. "Right lobe liver nodule." A 0.4 x 0.4 x 0.3 cm fragment of tan-red tissue entirely frozen in cassette A1.

B. "Celiac lymph node." A 3.0 x 1.5 x 1.0

cm tan-pink lymph node wi

Microscopic Description: Procedure: Pancreaticoduodenectomy (Whipple resection)

Tumor location: Head

Tumor size (greatest dimension): 3.5 cm

Histologic type: Ductal adenocarcinoma

Histologic grade: Moderately differentiated

Microscopic tumor extension: Invades peripancreatic soft tissues. Invades duodenal wall extending to the mucosa.

Surgical margins:

Distal pancreas margin: Free of neoplasm

Common bile duct margin: Free of neoplasm

Stomach/duodenum margin: Free of neoplasm

Retroperitoneal margins: Free of neoplasm

Uncinate groove: Free of neoplasm by 2 mm

Angiolymphatic spread: Yes

Perineural spread: Yes

Treatment effect: No prior treatment

TNM Staging:

Tumor extent: pT3: duodenum transmurally

LYMPH NODES:

Peripancreatic superior: 0 of 4 contain metastases

Peripancreatic inferior: 2 of 3 contain metastases

ICD O-3

Adenocarcinoma, duct NOS
8500/3

Site: Pancreas head
C25.0

8/21/13

[page 2 of 3]
Pancreaticoduodenal anterior: 0 of 8 contain metastases

Pancreaticoduodenal posterior: 2 of 7 contain metastases

Other findings: Atrophy, fibrosis, chronic pancreatitis, duct dilatation,
ductal dysplasia (PanIN type II and III)

AJCC stage: Stage IIB (T3 N1 M0)

Other organs:

Gastric antrum: Multifocal atrophic gastritis.

Diagnosis Details: Liver (Right lobe, A): Negative for malignancy

Lymph Nodes (Celiac and portal, B-C): Negative for metastasis

Galbladder (D): Acute and chronic cholecystitis with polypoid cholesterosis and diverticula, negative for dysplasia

Common Hepatic Duct Margin (

Comments: FROZEN SECTION DIAGNOSIS
LOBE NODULE): FAVOR BENIGN NODULE.

A. LIVER (RIGHT

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Whipple resection

Tumor site: Head

Tumor size: 3.5 x 2.5 x 2.5 cm

Histologic type: Adenocarcinoma, ductal type

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: 4/22 positive for metastasis (Peripancreatic superior, peripancreatic inferior, 4/22)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

[page 3 of 3]
Additional pathologic findings: Microscopic tumor extension: Invades peripancreatic soft tissues.
Invades duodenal wall extending to the mucosa.

Comments: None

Reviewed Initials	LM	

Source: NCI Genomic Data Commons file 13964e69-3732-40b3-8782-59683c85263f (TCGA-FB-A78T.E78A8131-436B-4A9B-8F28-986EAD34516D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).